TCGA case TCGA-24-0975 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6a57948c-0dc5-4ea2-8043-380f26763752

Demographics
Sex at birth: female; Race: white; Age at index: 58 years; Vital status: Dead; Days to death: 663 days (1.8 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,417 days); Year of diagnosis: 2004; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Number of cycles: 8; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 22 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Number of cycles: 8; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 22 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 564 days (1.5 years); Days to treatment end: 576 days (1.6 years); Treatment dose: 3,000 cGy; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment end: 611 days (1.7 years); Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment end: 611 days (1.7 years); Number of cycles: 3; Route of administration: Intravenous.

Follow-up (1 entry)
- Days to follow up: 663 days (1.8 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-0975-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.7.
  Slide TCGA-24-0975-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-24-0975-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-24-0975-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 0.8; Shortest dimension: 0.5. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-24-0975-01B-01-BS1: Section location: Top; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-24-0975-01B-02-BS2: Section location: Bottom; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-24-0975-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Radiation treatment: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Progression, Recurrence.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-0975-01): tumor purity 0.42, ploidy 1.82, whole-genome doublings 0 (call status: legacy_call).
